Somatic mutation profile of tumor specimen 0DHV6F from CCDI case PBBUNC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.7 years (5,736 days).
Specimen 0DHV6F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b48fff48-9568-4fe8-b08a-b7e789aaaafc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHV66 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d59b37de-4dbf-4011-9c0c-2f99edb56b75

The open-access MAF lists 51 somatic variants for this specimen: 32 protein-altering or splice-affecting, 9 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 4, Intron 4, 5'UTR 3, Frame Shift Del 2, 3'Flank 1, 3'UTR 1, RNA 1, Frame Shift Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 444/474 reads (94%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.4118G>A p.R1373H | Missense Mutation (SNP) | VAF 236/510 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201391209, COSV70025736; called by muse, mutect2, varscan2
- ADAMTS2 | c.1757G>A p.R586H | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749842152, COSV99281726; called by muse, mutect2, varscan2
- ADGRA2 | c.623G>A p.R208H | Missense Mutation (SNP) | VAF 105/285 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs766009635; called by muse, mutect2, varscan2
- ANKRD9 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.683); catalogued as rs1362855982; called by muse, mutect2, varscan2
- CDH7 | c.1490G>C p.G497A | Missense Mutation (SNP) | VAF 39/282 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV59882917, COSV59887056; called by muse, mutect2, varscan2
- CGB2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/541 reads (3%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.013); catalogued as rs1205456854; called by muse, mutect2
- DNAH1 | c.7726C>T p.R2576C | Missense Mutation (SNP) | VAF 205/402 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs753944292; called by muse, mutect2, varscan2
- EPPK1 | c.5432G>A p.R1811Q | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.051); catalogued as rs200136005, COSV73261037; called by muse, mutect2, varscan2
- KCNH8 | c.2716C>T p.R906W | Missense Mutation (SNP) | VAF 54/446 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.339); catalogued as rs373832681; called by muse, varscan2
- KDM4D | c.694C>G p.P232A | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV58634333; called by muse, mutect2, varscan2
- MCHR2 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 91/836 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV99912879; called by muse, mutect2, varscan2
- MUC16 | c.21622G>A p.A7208T | Missense Mutation (SNP) | VAF 88/346 reads (25%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV67457309; called by muse, mutect2, varscan2
- MUC5B | c.15109G>A p.V5037I | Missense Mutation (SNP) | VAF 45/354 reads (13%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs200849036; called by muse, mutect2, varscan2
- NRP1 | c.719C>T p.S240L | Missense Mutation (SNP) | VAF 58/539 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs775178016, COSV55162495; called by muse, mutect2, varscan2
- PPP1R9A | c.1166A>C p.N389T | Missense Mutation (SNP) | VAF 112/430 reads (26%) | SIFT tolerated (0.61); PolyPhen benign (0.01); catalogued as rs771016987; called by muse, mutect2, varscan2
- RASSF5 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 37/498 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.046); catalogued as rs570039354, COSV58798296; called by muse, mutect2
- RESF1 | c.4775G>A p.R1592H | Missense Mutation (SNP) | VAF 52/474 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs974575885, COSV57021198; called by muse, mutect2, varscan2
- SELENON | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 138/652 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs752156505; called by muse, mutect2, varscan2
- WRAP73 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 127/634 reads (20%) | catalogued as rs777673543; called by muse, mutect2, varscan2
- CDH19 | c.436C>A p.P146T | Missense Mutation (SNP) | VAF 222/416 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHD3 | c.2554dup p.Q852Pfs*12 | Frame Shift Ins (INS) | VAF 82/322 reads (25%) | called by mutect2, varscan2
- HELZ2 | c.2630C>T p.T877I (on ENST00000467148 / NM_001037335.2; = p.T308I on NM_033405.3) | Missense Mutation (SNP) | VAF 44/274 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- KAT6B | c.3606_3609del p.T1203Rfs*21 | Frame Shift Del (DEL) | VAF 200/487 reads (41%) | called by mutect2, varscan2
- LAMC3 | c.4357del p.E1453Sfs*12 | Frame Shift Del (DEL) | VAF 186/388 reads (48%) | called by mutect2, varscan2
- LAS1L | c.1561G>T p.E521* | Nonsense Mutation (SNP) | VAF 39/202 reads (19%) | called by muse, mutect2, varscan2
- LRIG1 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 195/472 reads (41%) | called by muse, mutect2, varscan2
- MUC22 | c.3629C>G p.A1210G | Missense Mutation (SNP) | VAF 435/813 reads (54%) | SIFT tolerated (0.45); called by muse, mutect2, varscan2
- TERT | c.362G>T p.S121I | Missense Mutation (SNP) | VAF 10/219 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- TFAP2D | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 207/473 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- XRCC6 | c.1777G>A p.G593R | Missense Mutation (SNP) | VAF 52/404 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- ZNF600 | c.1691G>A p.S564N | Missense Mutation (SNP) | VAF 32/244 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- AATK | c.1698C>T p.G566= (on ENST00000326724 / NM_001080395.3; = p.G463= on NM_004920.2) | Silent (SNP) | VAF 19/188 reads (10%) | catalogued as rs1414146145; called by muse, mutect2, varscan2
- ALKBH2 | c.385C>T p.L129= | Silent (SNP) | VAF 205/442 reads (46%) | catalogued as rs780699488; called by muse, mutect2, varscan2
- ELOA2 | c.2211G>A p.P737= | Silent (SNP) | VAF 11/147 reads (7%) | catalogued as rs1041227538; called by muse, mutect2
- FAP | c.633T>A p.A211= | Silent (SNP) | VAF 22/319 reads (7%) | catalogued as rs201505467; called by muse, mutect2
- MYBPC1 | c.225C>A p.I75= (on ENST00000550270 / NM_206820.2; = p.I100= on NM_002465.4) | Silent (SNP) | VAF 188/416 reads (45%) | catalogued as COSV100637852; called by muse, mutect2, varscan2
- OTUD6A | c.822G>A p.P274= | Silent (SNP) | VAF 110/230 reads (48%) | called by muse, mutect2, varscan2
- SLFN14 | c.1227C>G p.L409= | Silent (SNP) | VAF 56/465 reads (12%) | called by muse, mutect2, varscan2
- ZBTB40 | c.2577C>T p.T859= | Silent (SNP) | VAF 19/476 reads (4%) | catalogued as rs1436507050, COSV65144752; called by muse, mutect2
- ZNF600 | c.1299G>A p.K433= | Silent (SNP) | VAF 29/550 reads (5%) | called by muse, mutect2
- C5orf60 | n.993G>A | RNA (SNP) | VAF 116/283 reads (41%) | called by muse, mutect2, varscan2
- CHD2 | c.1153+25G>T | Intron (SNP) | VAF 96/365 reads (26%) | called by muse, mutect2, varscan2
- COL6A1 | c.739-23G>A | Intron (SNP) | VAF 42/534 reads (8%) | catalogued as rs753305527; called by muse, mutect2
- CYP2E1 | c.178-54C>G | Intron (SNP) | VAF 21/161 reads (13%) | called by muse, mutect2, varscan2
- ECE1 | c.-78G>T | 5'UTR (SNP) | VAF 93/206 reads (45%) | called by muse, mutect2
- FAM13B | c.-27G>A | 5'UTR (SNP) | VAF 132/231 reads (57%) | called by muse, varscan2
- FBXO4 | c.-10C>A | 5'UTR (SNP) | VAF 22/272 reads (8%) | called by muse, mutect2
- FCHSD1 | c.*1840C>T | 3'UTR (SNP) | VAF 168/393 reads (43%) | called by muse, mutect2, varscan2
- LGALS13 | c.93-44G>A | Intron (SNP) | VAF 16/76 reads (21%) | catalogued as rs757263755; called by muse, mutect2, varscan2
- TCHHL1 | chr1:152079767 G>A | 3'Flank (SNP) | VAF 130/679 reads (19%) | catalogued as rs983607291; called by muse, mutect2, varscan2
